Somatic mutation profile of tumor specimen ALCH-B1KV-TTP1-A (aliquot ALCH-B1KV-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1KV, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.8 years (27,313 days).
Specimen ALCH-B1KV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ea34539-4af3-4aee-9fca-8879d0a26e05.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1KV-NB1-A (Blood Derived Normal), aliquot ALCH-B1KV-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b83b89c9-f060-4dda-b38b-4391e7b430de

The open-access MAF lists 420 somatic variants for this specimen: 294 protein-altering or splice-affecting, 77 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 258, Silent 77, Intron 22, Nonsense Mutation 19, RNA 14, Splice Site 9, 3'UTR 6, Frame Shift Del 3, Splice Region 3, 3'Flank 3, 5'Flank 2, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AAGAB | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.678); catalogued as rs1046940979; called by muse, mutect2
- ACE | c.3691+1G>A p.X1231_splice | Splice Site (SNP) | VAF 9/55 reads (16%) | catalogued as CS133306; called by muse, mutect2, varscan2
- ADAM18 | c.2015C>A p.S672Y | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV55854489; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2098G>C p.E700Q | Missense Mutation (SNP) | VAF 59/391 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.799); catalogued as COSV65892063; called by muse, mutect2, varscan2
- AGTR1 | c.862A>G p.I288V | Missense Mutation (SNP) | VAF 65/401 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs758763207; called by muse, mutect2, varscan2
- BCL6B | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1431084194, COSV53427242; called by muse, mutect2
- BET1L | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs954701165; called by muse, mutect2, varscan2
- CACNA1F | c.2192G>T p.G731V | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59906963; called by muse, mutect2, varscan2
- CCDC168 | c.1702G>T p.G568C | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV101468894; called by muse, mutect2
- CD5L | c.496G>T p.G166C | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100941000, COSV63823423; called by muse, mutect2
- CDH18 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs375530344, COSV56975305; called by muse, mutect2
- CDX4 | c.812G>T p.G271V | Missense Mutation (SNP) | VAF 27/268 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100999101; called by muse, mutect2
- CEP83 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 11/299 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV60409411; called by muse, mutect2
- CNTNAP5 | c.2709G>T p.E903D | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV101443317; called by muse, mutect2
- COL22A1 | c.3502G>T p.G1168* | Nonsense Mutation (SNP) | VAF 46/360 reads (13%) | catalogued as COSV57342729; called by muse, mutect2, varscan2
- COQ5 | c.408G>C p.Q136H | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.549); catalogued as COSV56018872; called by muse, mutect2
- CPN2 | c.1034G>T p.G345V | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs768640281; called by muse, mutect2, varscan2
- CTNND1 | c.2524G>C p.E842Q (on ENST00000399050 / NM_001085458.2; = p.E836Q on NM_001331.3) | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV62382728, COSV62382958; called by muse, mutect2
- DCAF12L1 | c.134C>A p.P45Q | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.149); catalogued as COSV100948492, COSV99058403; called by muse, mutect2
- DDX20 | c.553G>T p.V185F | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63831446; called by muse, mutect2
- DHX29 | c.1102G>C p.D368H | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52420468; called by muse, mutect2
- DNAI4 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV64021515; called by muse, mutect2, varscan2
- DYNC1I1 | c.1258C>A p.L420M | Missense Mutation (SNP) | VAF 25/218 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs767469710; called by muse, mutect2, varscan2
- EGLN2 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100393738; called by muse, mutect2, varscan2
- ELOVL1 | c.638C>G p.S213* | Nonsense Mutation (SNP) | VAF 10/132 reads (8%) | catalogued as COSV60522718; called by muse, mutect2
- EPB41L3 | c.2803C>A p.H935N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV59443072, COSV59464558; called by muse, mutect2
- FASTKD3 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 37/231 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755002184; called by muse, mutect2, varscan2
- FATE1 | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1377473403; called by muse, mutect2, varscan2
- FLG2 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 17/115 reads (15%) | catalogued as rs200529004, COSV66167566; called by muse, mutect2, varscan2
- FOXE1 | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as COSV64300423, COSV64300473; called by muse, mutect2, varscan2
- FREM1 | c.5689C>T p.L1897F | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs370675981; called by muse, mutect2, varscan2
- GFRA1 | c.832C>G p.L278V | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.443); catalogued as COSV62604350; called by muse, mutect2
- GPR6 | c.1064G>A p.R355H | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); catalogued as COSV51571247, COSV51573087; called by muse, mutect2
- GPS2 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV59753334; called by muse, mutect2
- GRN | c.329G>C p.R110P | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as CM084959; called by muse, mutect2, varscan2
- HERC2 | c.11752C>G p.L3918V | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs766759949; called by muse, mutect2
- HNF4A | c.1099G>T p.D367Y | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as CM108586; called by muse, mutect2
- IGKV1D-8 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 28/308 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs769051005; called by muse, mutect2
- JAK3 | c.2560G>A p.V854M | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs370332355; called by muse, mutect2, varscan2
- KIF2B | c.623C>A p.P208H | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as rs761851351; called by muse, mutect2
- KLF8 | c.512A>G p.K171R | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV63847515; called by muse, mutect2
- KLRG2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.832); catalogued as rs778875071; called by muse, mutect2
- KRT2 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 11/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548408; called by muse, mutect2
- KRTAP27-1 | c.285C>A p.C95* | Nonsense Mutation (SNP) | VAF 14/152 reads (9%) | catalogued as COSV67001724; called by muse, mutect2
- LAMA1 | c.7282C>T p.R2428C | Missense Mutation (SNP) | VAF 84/498 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs762532829, COSV67538088; called by muse, mutect2, varscan2
- LIG1 | c.920G>T p.R307L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as COSV54395940; called by muse, mutect2, varscan2
- LRP1B | c.11072G>A p.W3691* | Nonsense Mutation (SNP) | VAF 22/300 reads (7%) | catalogued as COSV67281226; called by muse, mutect2
- METTL21C | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.371); catalogued as rs772807635, COSV57432601; called by muse, mutect2, varscan2
- MGAM | c.4557G>A p.W1519* | Nonsense Mutation (SNP) | VAF 12/218 reads (6%) | catalogued as rs1188514985, COSV101527380; called by muse, mutect2
- MUC15 | c.242G>T p.S81I | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99846702; called by muse, mutect2, varscan2
- MVP | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372484922; called by mutect2, varscan2
- MYC | c.830C>T p.S277L (on ENST00000377970; = p.S292L on NM_002467.6) | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.273); catalogued as COSV52372044, COSV99421903; called by muse, mutect2
- NID2 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as rs759815670, COSV53495297, COSV53504393; called by muse, mutect2
- NLRP2 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54757562; called by muse, mutect2, varscan2
- NOTCH4 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV66678452; called by muse, mutect2, varscan2
- OGT | c.2012C>A p.A671E | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65481915; called by muse, mutect2
- OR10G7 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1274430707; called by muse, mutect2
- OR2T12 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as COSV58777521; called by muse, mutect2
- OR2W3 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64456613; called by muse, varscan2
- OR4N2 | c.778C>G p.R260G | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV60049790; called by muse, mutect2
- P2RY12 | c.485T>G p.L162R | Missense Mutation (SNP) | VAF 94/313 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56378818; called by muse, mutect2, varscan2
- PAH | c.228G>T p.E76D | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as BM0974125; called by muse, mutect2, varscan2
- PCF11 | c.919C>A p.H307N | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.728); catalogued as rs369620312, COSV100018408; called by muse, mutect2
- PHEX | c.1483-1G>T p.X495_splice | Splice Site (SNP) | VAF 14/353 reads (4%) | catalogued as CS123632; called by muse, mutect2
- POTEH | c.1286G>A p.G429E | Missense Mutation (SNP) | VAF 20/573 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.052); catalogued as COSV100625129; called by muse, mutect2
- PSG8 | c.473C>G p.P158R | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1187722601, COSV60614765; called by muse, mutect2
- PTGES3L-AARSD1 | c.532G>A p.D178N (on ENST00000421990 / NM_001136042.2; = p.D160N on NM_025267.3) | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs548746113; called by muse, mutect2, varscan2
- ROBO3 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.421); catalogued as COSV67300608; called by muse, mutect2
- RSC1A1 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.059); catalogued as rs200225759; called by muse, mutect2, varscan2
- RUFY3 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV101121434; called by muse, mutect2
- SAP130 | c.2762G>T p.R921L | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV52095364, COSV99385377; called by muse, mutect2
- SBF2 | c.716G>C p.R239T | Missense Mutation (SNP) | VAF 24/347 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV56298344; called by muse, mutect2
- SIM1 | c.1249C>A p.P417T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.137); catalogued as COSV53496760; called by muse, mutect2, varscan2
- SLC2A2 | c.1069-1G>A p.X357_splice | Splice Site (SNP) | VAF 43/467 reads (9%) | catalogued as CS116203; called by muse, mutect2
- SPON1 | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 13/280 reads (5%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); catalogued as rs148033537, COSV59960524; called by muse, mutect2
- STARD6 | c.415C>G p.P139A | Missense Mutation (SNP) | VAF 9/258 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100323399; called by muse, mutect2
- SVEP1 | c.1930+1G>T p.X644_splice | Splice Site (SNP) | VAF 5/105 reads (5%) | catalogued as COSV57028225; called by muse, mutect2
- SYCP3 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1231268680; called by muse, mutect2, varscan2
- TAF1 | c.3142C>T p.R1048C (on ENST00000373790 / NM_138923.4; = p.R1069C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52110484; called by muse, mutect2
- TGFBR3 | c.2047A>G p.M683V | Missense Mutation (SNP) | VAF 27/356 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.005); catalogued as rs1186532685; called by muse, mutect2
- TNR | c.3019C>T p.R1007W | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs774052903, COSV54873532; called by muse, mutect2, varscan2
- TXNRD1 | c.1308G>T p.T436= (on ENST00000525566 / NM_001093771.3; = p.T338= on NM_003330.4) | Splice Region (SNP) | VAF 12/154 reads (8%) | catalogued as COSV100723577, COSV61601215; called by muse, mutect2
- UGT3A2 | c.675C>G p.I225M | Missense Mutation (SNP) | VAF 17/375 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56930677; called by muse, mutect2
- USH1C | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.336); catalogued as rs1365223252, COSV50030065; called by muse, mutect2
- USH2A | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 19/300 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.049); catalogued as rs765098958, COSV56382993; called by muse, mutect2
- UTP20 | c.3139G>A p.G1047R | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs776025445; called by muse, mutect2, varscan2
- VLDLR | c.2572C>T p.H858Y | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.834); catalogued as rs1563768980; called by muse, mutect2, varscan2
- WRN | c.968C>G p.S323* | Nonsense Mutation (SNP) | VAF 24/202 reads (12%) | catalogued as COSV53302808; called by muse, mutect2, varscan2
- WTIP | c.979C>G p.P327A | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1445107371; called by muse, mutect2
- ZMYM6 | c.3816G>C p.M1272I | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV64121134; called by muse, mutect2
- ZNF18 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs1458495225; called by muse, mutect2
- ZNF626 | c.882C>G p.F294L | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV74129414; called by muse, mutect2
- ZNF679 | c.641G>A p.C214Y | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.057); catalogued as COSV55376451; called by muse, mutect2
- AADAT | c.962+2T>C p.X321_splice | Splice Site (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- AC024592.3 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- ADAM29 | c.1778C>A p.P593H | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADD2 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.053); called by muse, mutect2
- ADGRB1 | c.4355G>T p.S1452I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AFF2 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 7/190 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2
- AGMO | c.506C>A p.T169N | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- ALG5 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 28/450 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANTXR1 | c.234G>C p.L78F | Missense Mutation (SNP) | VAF 43/411 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARAF | c.700-2A>T p.X234_splice | Splice Site (SNP) | VAF 36/178 reads (20%) | called by muse, mutect2, varscan2
- ARL13A | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARMCX3 | c.1045G>T p.G349* | Nonsense Mutation (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- ATG2A | c.2477G>T p.S826I | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ATN1 | c.508C>G p.Q170E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, varscan2
- ATP11C | c.977G>T p.W326L | Missense Mutation (SNP) | VAF 34/323 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.075); called by muse, mutect2
- ATP13A5 | c.1464T>A p.T488= | Splice Region (SNP) | VAF 11/160 reads (7%) | called by muse, mutect2
- ATP2B3 | c.1879dup p.R627Pfs*40 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by pindel, varscan2
- BATF3 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.519); called by muse, mutect2
- BLOC1S5 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- BRDT | c.878G>C p.W293S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BUB1B | c.2443T>A p.L815I | Missense Mutation (SNP) | VAF 21/352 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- C1QL2 | c.864G>T p.*288Yext*30 | Nonstop Mutation (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- CAB39 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2
- CCDC180 | c.3499G>A p.D1167N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.33); called by muse, mutect2
- CCL19 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); called by muse, mutect2
- CD200 | c.78T>G p.N26K | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); called by muse, mutect2
- CDH23 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CEP350 | c.6820G>T p.A2274S | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CLEC1A | c.164T>A p.L55Q | Missense Mutation (SNP) | VAF 102/392 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CLMN | c.1077G>A p.M359I | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2
- COL11A2 | c.4014+1G>T p.X1338_splice (on ENST00000341947 / NM_080680.3; = p.X1231_splice on NM_080679.2) | Splice Site (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- COL22A1 | c.3598C>A p.P1200T | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2
- CPED1 | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- CPM | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 13/267 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); called by muse, mutect2
- CSMD3 | c.2652G>T p.W884C (on ENST00000297405 / NM_001363185.1; = p.W780C on NM_052900.3) | Missense Mutation (SNP) | VAF 37/455 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CUX1 | c.2518G>C p.E840Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, varscan2
- CX3CR1 | c.950G>T p.G317V | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.178); called by muse, mutect2
- DCDC1 | c.2669A>T p.K890M | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- DDX10 | c.590C>T p.T197I | Missense Mutation (SNP) | VAF 12/281 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DEF6 | c.556G>C p.E186Q | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.15); called by muse, mutect2
- DGAT2 | c.228G>T p.W76C | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- DHX36 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLG3 | c.1433A>G p.H478R (on ENST00000374360 / NM_021120.4; = p.H141R on NM_020730.3) | Missense Mutation (SNP) | VAF 13/246 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DRP2 | c.625A>C p.S209R | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.829); called by muse, mutect2
- DSG2 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 23/418 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DUOX2 | c.2876A>T p.N959I | Missense Mutation (SNP) | VAF 15/258 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.001); called by muse, mutect2
- EIF2AK4 | c.3230G>C p.R1077T | Missense Mutation (SNP) | VAF 22/375 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2
- ELAVL4 | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 16/241 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EPHA10 | c.2691C>A p.H897Q | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- EPHA5 | c.2378A>T p.D793V | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- EPS8 | c.2207C>T p.S736L | Missense Mutation (SNP) | VAF 6/120 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- EXOSC3 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- F13B | c.1711A>G p.M571V | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- F5 | c.3185G>C p.R1062T | Missense Mutation (SNP) | VAF 19/251 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); called by muse, mutect2
- FAM135B | c.2142G>T p.L714F | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); called by muse, mutect2
- FANCG | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 27/324 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- FATE1 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGA | c.1971G>C p.K657N | Missense Mutation (SNP) | VAF 29/315 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2
- FRMD7 | c.1382C>G p.S461C | Missense Mutation (SNP) | VAF 13/170 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.706); called by muse, mutect2
- GDAP1 | c.992G>T p.G331V | Missense Mutation (SNP) | VAF 23/474 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GIMAP7 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 19/282 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- GJA8 | c.12G>T p.W4C | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLI1 | c.1561A>T p.S521C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); called by muse, mutect2
- GOLGA8S | c.814C>A p.H272N | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- GPR88 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.951); called by muse, mutect2
- GPRASP1 | c.2587G>C p.E863Q | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GRM8 | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 13/164 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.065); called by muse, mutect2
- HARS2 | c.755A>T p.H252L | Missense Mutation (SNP) | VAF 45/482 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2
- HES1 | c.146G>C p.R49T | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN1 | c.10934C>G p.S3645* | Nonsense Mutation (SNP) | VAF 14/356 reads (4%) | called by muse, mutect2
- HMGN5 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.021); called by muse, mutect2
- HOXC9 | c.137A>T p.D46V | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); called by muse, mutect2
- HTR1E | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- IDO1 | c.1029G>C p.R343S | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV3D-20 | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 10/310 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- IL12A | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2
- IL32 | c.623C>T p.S208F (on ENST00000396890 / NM_001308078.4; = p.S162F on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.084); called by muse, mutect2
- IPO8 | c.2381C>G p.P794R | Missense Mutation (SNP) | VAF 45/463 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2
- ITFG1 | c.1510G>T p.G504C | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- JCAD | c.1053G>T p.Q351H | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KBTBD7 | c.176C>G p.A59G | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- KCNA4 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- KCND1 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2
- KCNIP3 | c.738G>A p.M246I | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KDM2B | c.3764C>G p.S1255C | Missense Mutation (SNP) | VAF 23/190 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- KIAA0100 | c.929A>T p.Y310F | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KRT6A | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 18/397 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2
- LDAH | c.154G>T p.G52C | Missense Mutation (SNP) | VAF 8/119 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LHCGR | c.680+3G>A | Splice Region (SNP) | VAF 18/179 reads (10%) | called by muse, mutect2, varscan2
- LRP2 | c.5761C>A p.L1921M | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.828); called by muse, mutect2
- LRTM2 | c.21C>A p.S7R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LYN | c.508A>G p.R170G | Missense Mutation (SNP) | VAF 14/278 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LYPLAL1 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MANBA | c.2383C>G p.L795V (on ENST00000642252; = p.L749V on NM_005908.4) | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.073); called by muse, mutect2
- MCC | c.1928A>G p.K643R | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.003); called by muse, mutect2
- MGA | c.4832C>T p.A1611V | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- MLLT6 | c.2399_2420del p.K800Tfs*97 | Frame Shift Del (DEL) | VAF 8/92 reads (9%) | called by mutect2, pindel
- MPHOSPH9 | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 21/297 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2
- MTMR9 | c.1042C>A p.Q348K | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- MTUS2 | c.411T>G p.N137K | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- MUC17 | c.12481C>A p.P4161T | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYL5 | c.38C>G p.A13G | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, varscan2
- NAV3 | c.4406C>G p.S1469C | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- NAXD | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCF4 | c.396C>G p.F132L | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- NCOA6 | c.5549G>A p.G1850E | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCOA6 | c.1631C>G p.S544* | Nonsense Mutation (SNP) | VAF 17/219 reads (8%) | called by muse, mutect2
- NEB | c.15157G>C p.E5053Q | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NEXN | c.1940A>C p.E647A | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOD2 | c.2414T>A p.I805N | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); called by muse, mutect2
- NR1H4 | c.509del p.V170Gfs*11 (on ENST00000551379 / NM_001206993.2; = p.V160Gfs*11 on NM_005123.4) | Frame Shift Del (DEL) | VAF 20/207 reads (10%) | called by mutect2, pindel, varscan2
- NR3C1 | c.1652C>T p.S551F | Missense Mutation (SNP) | VAF 45/441 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- NSF | c.1300A>G p.K434E | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by mutect2, varscan2
- NTAN1 | c.185-2A>T p.X62_splice | Splice Site (SNP) | VAF 24/181 reads (13%) | called by muse, mutect2, varscan2
- NUP205 | c.1271G>T p.S424I | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.393); called by muse, mutect2
- NUP98 | c.3901G>C p.E1301Q (on ENST00000359171 / NM_001365126.1; = p.E1284Q on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2
- OCRL | c.2321C>T p.T774I | Missense Mutation (SNP) | VAF 40/334 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ODF2 | c.1805T>G p.I602S (on ENST00000434106 / NM_153433.2; = p.I578S on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.088); called by muse, mutect2
- OR52N1 | c.95C>G p.P32R | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- OR52R1 | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2
- OR52R1 | c.570G>T p.L190F | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR5AR1 | c.665T>C p.L222P | Missense Mutation (SNP) | VAF 13/201 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.109); called by muse, mutect2
- OSBPL11 | c.2239G>T p.E747* | Nonsense Mutation (SNP) | VAF 20/274 reads (7%) | called by muse, mutect2
- P2RY4 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.147); called by muse, mutect2
- PAQR3 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCDH17 | c.2899G>T p.A967S | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PDE6C | c.1871T>A p.L624H | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PGM2L1 | c.287A>T p.Y96F | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- PHF19 | c.544G>T p.E182* | Nonsense Mutation (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- PHF6 | c.559A>T p.T187S (on ENST00000332070 / NM_032458.3; = p.T188S on NM_032335.3) | Missense Mutation (SNP) | VAF 21/289 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.039); called by muse, mutect2
- PHKA2 | c.1693C>T p.P565S | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); called by muse, mutect2
- PKD2L1 | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- PKHD1 | c.11617G>T p.A3873S | Missense Mutation (SNP) | VAF 32/317 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PLPPR4 | c.1021A>T p.R341* | Nonsense Mutation (SNP) | VAF 7/103 reads (7%) | called by muse, mutect2
- PLSCR4 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 13/273 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PNCK | c.538G>T p.A180S (on ENST00000340888 / NM_001366975.1; = p.A263S on NM_001039582.3) | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- POLR3B | c.2857G>A p.V953M | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2
- POTEM | c.943T>G p.C315G | Missense Mutation (SNP) | VAF 56/506 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- PPIB | c.608G>T p.G203V | Missense Mutation (SNP) | VAF 28/292 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PRG4 | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 70/507 reads (14%) | called by muse, mutect2, varscan2
- PRKCE | c.677A>T p.Q226L | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRKCQ | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 109/422 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PRR36 | c.1943C>G p.S648C | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- PSEN1 | c.644G>T p.W215L | Missense Mutation (SNP) | VAF 26/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRQ | c.3890C>G p.T1297S (on ENST00000616559; = p.T1255S on NM_001145026.2) | Missense Mutation (SNP) | VAF 29/308 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.444); called by muse, mutect2
- PYGM | c.1078A>T p.M360L | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- RBM33 | c.3448C>T p.Q1150* | Nonsense Mutation (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- RELB | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 5/110 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- RELN | c.7966G>C p.D2656H | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- RGS2 | c.389C>G p.S130* | Nonsense Mutation (SNP) | VAF 26/650 reads (4%) | called by muse, mutect2
- RNF175 | c.893G>C p.G298A | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); called by muse, mutect2
- RNF214 | c.784C>G p.Q262E | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- RYR3 | c.1770G>T p.K590N | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SATB2 | c.366G>T p.R122S | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SEL1L3 | c.2074C>A p.Q692K | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- SEPTIN6 | c.1159A>G p.K387E | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SH3GL3 | c.403G>C p.V135L | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); called by muse, mutect2
- SHC1 | c.325_332del p.Q109Efs*32 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | called by mutect2, pindel, varscan2
- SLC2A10 | c.1339G>T p.A447S | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC39A6 | c.1765G>C p.D589H | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- SLC7A3 | c.248G>T p.C83F | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- SMARCA1 | c.2004G>T p.M668I | Missense Mutation (SNP) | VAF 11/286 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.012); called by muse, mutect2
- SNCB | c.122-2A>G p.X41_splice | Splice Site (SNP) | VAF 13/158 reads (8%) | called by muse, mutect2
- SOX30 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- SSR1 | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 45/431 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- ST8SIA6 | c.992C>A p.A331E | Missense Mutation (SNP) | VAF 13/500 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- STON1-GTF2A1L | c.3535G>T p.D1179Y | Missense Mutation (SNP) | VAF 18/369 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- TAOK2 | c.3107G>T p.R1036L | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by mutect2, varscan2
- TBR1 | c.1084C>G p.P362A | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2
- TGM5 | c.1351C>T p.L451F (on ENST00000220420 / NM_201631.4; = p.L369F on NM_004245.4) | Missense Mutation (SNP) | VAF 19/211 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.06); called by muse, mutect2
- THAP6 | c.65G>T p.G22V | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- THOC2 | c.2881G>C p.D961H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TKTL2 | c.752G>C p.G251A | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- TLL1 | c.2827G>T p.D943Y | Missense Mutation (SNP) | VAF 50/360 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPO | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.9); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRAPPC8 | c.3672G>T p.E1224D | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2
- TRAV12-3 | c.107C>A p.P36Q | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.953); called by muse, mutect2
- TRGC1 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); called by muse, mutect2
- TRMT2B | c.338G>C p.R113T | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.005); called by muse, mutect2
- TSPAN2 | c.527A>T p.D176V | Missense Mutation (SNP) | VAF 27/269 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- TTC19 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 42/426 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TUT4 | c.726G>A p.M242I | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- TUT7 | c.2518G>C p.E840Q | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2
- UACA | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- UGGT2 | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- UGT3A1 | c.1190A>T p.N397I | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- USH2A | c.10502G>T p.G3501V | Missense Mutation (SNP) | VAF 28/261 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- USP24 | c.3364G>T p.D1122Y | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- UTP14A | c.1559A>C p.E520A | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- VAC14 | c.623T>C p.I208T | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); called by muse, mutect2
- VPS8 | c.1235C>A p.S412* (on ENST00000625842 / NM_001349294.1; = p.S410* on NM_015303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2, varscan2
- VSIG8 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 26/300 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2
- ZBTB41 | c.1333C>T p.H445Y | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZEB1 | c.1948G>T p.G650C | Missense Mutation (SNP) | VAF 22/750 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); called by muse, mutect2
- ZMYM3 | c.4020C>G p.D1340E | Missense Mutation (SNP) | VAF 5/118 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.485); called by muse, mutect2
- ZNF114 | c.434C>A p.S145Y | Missense Mutation (SNP) | VAF 48/169 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ZNF225 | c.1416G>C p.L472F | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2
- ZNF521 | c.1258G>C p.V420L | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF610 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.562); called by muse, mutect2
- ZNF735 | c.862A>T p.K288* | Nonsense Mutation (SNP) | VAF 14/287 reads (5%) | called by muse, mutect2
- ZNF81 | c.106C>A p.Q36K | Missense Mutation (SNP) | VAF 81/341 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- ABCA10 | c.1326A>G p.G442= | Silent (SNP) | VAF 30/312 reads (10%) | called by muse, mutect2
- ADAM23 | c.1806C>A p.G602= | Silent (SNP) | VAF 31/353 reads (9%) | called by muse, mutect2
- ADCY9 | c.3750C>T p.V1250= | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- ADGRB3 | c.663C>A p.P221= | Silent (SNP) | VAF 7/102 reads (7%) | catalogued as COSV65385290, COSV65385428; called by muse, mutect2
- AGMO | c.507T>A p.T169= | Silent (SNP) | VAF 21/162 reads (13%) | called by muse, mutect2, varscan2
- ANKRD34C | c.666C>T p.T222= | Silent (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
- BNC2 | c.1917T>A p.P639= | Silent (SNP) | VAF 11/290 reads (4%) | called by muse, mutect2
- C8B | c.1350G>A p.Q450= | Silent (SNP) | VAF 20/173 reads (12%) | called by muse, mutect2, varscan2
- CALHM5 | c.6T>C p.D2= | Silent (SNP) | VAF 6/43 reads (14%) | called by muse, mutect2, varscan2
- CBY2 | c.513G>A p.E171= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- CCDC168 | c.1701G>T p.P567= | Silent (SNP) | VAF 24/254 reads (9%) | called by muse, mutect2
- CCDC33 | c.81T>A p.G27= | Silent (SNP) | VAF 8/54 reads (15%) | called by muse, varscan2
- CCNB1 | c.1221G>A p.S407= | Silent (SNP) | VAF 16/139 reads (12%) | catalogued as rs760563473; called by muse, mutect2, varscan2
- CDC25A | c.870G>A p.R290= | Silent (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- CDH10 | c.2076A>T p.P692= | Silent (SNP) | VAF 18/536 reads (3%) | called by muse, mutect2
- CHODL | c.252G>A p.L84= | Silent (SNP) | VAF 20/257 reads (8%) | catalogued as rs773436892; called by muse, mutect2
- CPS1 | c.4221A>T p.P1407= | Silent (SNP) | VAF 36/370 reads (10%) | catalogued as rs1252997852; called by muse, mutect2
- CUX1 | c.2421G>A p.L807= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV52908403; called by muse, varscan2
- CYP27C1 | c.36G>A p.P12= | Silent (SNP) | VAF 23/253 reads (9%) | catalogued as rs199656387, COSV58867854; called by muse, mutect2
- DGKK | c.876C>G p.P292= | Silent (SNP) | VAF 44/348 reads (13%) | called by muse, mutect2, varscan2
- DOCK11 | c.129G>T p.L43= | Silent (SNP) | VAF 17/260 reads (7%) | called by muse, mutect2
- DSCAML1 | c.117G>A p.G39= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- EBP | c.549C>G p.L183= | Silent (SNP) | VAF 15/89 reads (17%) | called by muse, mutect2, varscan2
- FAM71C | c.15T>C p.C5= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- FLRT2 | c.1434G>A p.L478= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs1388371841; called by muse, mutect2, varscan2
- IFIH1 | c.1740A>G p.Q580= | Silent (SNP) | VAF 16/148 reads (11%) | called by muse, mutect2
- IGLON5 | c.96C>T p.S32= | Silent (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- IL27RA | c.1020C>G p.T340= | Silent (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- KCND2 | c.93G>A p.P31= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100475093; called by muse, mutect2
- KLHL4 | c.138C>A p.T46= | Silent (SNP) | VAF 20/256 reads (8%) | catalogued as COSV64146581; called by muse, mutect2
- LENG1 | c.741C>T p.F247= | Silent (SNP) | VAF 11/71 reads (15%) | called by muse, mutect2, varscan2
- LUZP4 | c.852G>A p.E284= | Silent (SNP) | VAF 23/343 reads (7%) | called by muse, mutect2
- MAGEA12 | c.153G>A p.R51= | Silent (SNP) | VAF 7/123 reads (6%) | called by muse, mutect2
- METRN | c.240C>T p.I80= | Silent (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- MROH2B | c.4581C>A p.L1527= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as COSV101270527; called by muse, mutect2, varscan2
- MSRA | c.636G>C p.L212= | Silent (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2, varscan2
- MYBL1 | c.96C>G p.L32= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs1192621507; called by muse, varscan2
- MYO9B | c.5271C>G p.V1757= | Silent (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- NCOR1 | c.5787A>G p.A1929= | Silent (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- NOL4 | c.216G>T p.G72= | Silent (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- NSFL1C | c.594C>A p.L198= | Silent (SNP) | VAF 20/136 reads (15%) | called by muse, mutect2, varscan2
- NUS1 | c.492T>C p.C164= | Silent (SNP) | VAF 23/276 reads (8%) | called by muse, mutect2
- OR2T12 | c.135C>A p.L45= | Silent (SNP) | VAF 6/150 reads (4%) | called by muse, mutect2
- OR4K13 | c.108G>A p.V36= | Silent (SNP) | VAF 21/281 reads (7%) | called by muse, mutect2
- OR4K17 | c.771C>T p.I257= | Silent (SNP) | VAF 23/199 reads (12%) | called by muse, mutect2, varscan2
- OR56A3 | c.438C>A p.V146= | Silent (SNP) | VAF 32/358 reads (9%) | called by muse, mutect2
- OR5T1 | c.669C>A p.I223= | Silent (SNP) | VAF 17/259 reads (7%) | catalogued as COSV57304004; called by muse, mutect2
- PLCH1 | c.3249T>C p.S1083= (on ENST00000340059 / NM_001130960.2; = p.S1075= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as rs1173268614; called by muse, mutect2
- PLCL1 | c.2574G>A p.K858= | Silent (SNP) | VAF 26/278 reads (9%) | catalogued as rs1036042656; called by muse, mutect2
- PLS1 | c.633C>G p.V211= | Silent (SNP) | VAF 7/196 reads (4%) | called by muse, mutect2
- PRKCE | c.1671G>A p.G557= | Silent (SNP) | VAF 16/292 reads (5%) | catalogued as rs768844479; called by muse, mutect2
- PRX | c.1704G>T p.R568= | Silent (SNP) | VAF 19/140 reads (14%) | called by mutect2, varscan2
- PSME2 | c.114G>A p.Q38= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as rs1170972010; called by muse, mutect2
- QDPR | c.564G>A p.P188= | Silent (SNP) | VAF 14/229 reads (6%) | catalogued as rs1322741039; called by muse, mutect2
- RPS13 | c.55C>A p.R19= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV57180427; called by muse, varscan2
- RYR2 | c.6051G>T p.L2017= | Silent (SNP) | VAF 18/122 reads (15%) | called by muse, mutect2, varscan2
- SCML4 | c.111A>T p.P37= | Silent (SNP) | VAF 7/107 reads (7%) | called by muse, mutect2
- SEC24C | c.2049G>T p.L683= | Silent (SNP) | VAF 8/117 reads (7%) | called by muse, mutect2
- SETD1B | c.1227A>T p.P409= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- SGSM1 | c.160C>T p.L54= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs774274923, COSV68511462; called by mutect2, varscan2
- SLC12A3 | c.2535C>T p.L845= (on ENST00000563236 / NM_001126108.2; = p.L854= on NM_000339.3) | Silent (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- SMPD3 | c.1026C>T p.D342= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs774506167; called by mutect2, varscan2
- SNURF | c.30G>A p.L10= | Silent (SNP) | VAF 63/674 reads (9%) | catalogued as rs1423534843; called by muse, mutect2
- SOX3 | c.1101G>T p.L367= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- SPHKAP | c.4806C>A p.A1602= (on ENST00000392056 / NM_001142644.2; = p.A1573= on NM_030623.3) | Silent (SNP) | VAF 6/121 reads (5%) | catalogued as COSV100764115; called by muse, mutect2
- ST8SIA6 | c.993A>G p.A331= | Silent (SNP) | VAF 14/506 reads (3%) | called by muse, mutect2
- TAOK2 | c.3108A>T p.R1036= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, varscan2
- TECTA | c.5490G>A p.V1830= | Silent (SNP) | VAF 26/245 reads (11%) | called by muse, mutect2, varscan2
- TLR8 | c.1731A>G p.L577= (on ENST00000218032 / NM_138636.5; = p.L595= on NM_016610.4) | Silent (SNP) | VAF 4/69 reads (6%) | called by muse, mutect2
- TP63 | c.903A>T p.T301= | Silent (SNP) | VAF 74/404 reads (18%) | catalogued as COSV99288595; called by muse, mutect2, varscan2
- TPR | c.918A>T p.A306= | Silent (SNP) | VAF 40/510 reads (8%) | called by muse, mutect2
- TRAPPC12 | c.1137A>G p.Q379= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs375364620; called by muse, mutect2, varscan2
- TRIM4 | c.957A>G p.K319= | Silent (SNP) | VAF 10/58 reads (17%) | called by mutect2, varscan2
- TTC13 | c.852A>T p.I284= | Silent (SNP) | VAF 11/130 reads (8%) | called by muse, mutect2
- WDR49 | c.144C>G p.P48= (on ENST00000308378 / NM_001366158.1; = p.P389= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as rs768313751; called by muse, mutect2, varscan2
- XK | c.397C>A p.R133= | Silent (SNP) | VAF 11/212 reads (5%) | catalogued as CM004084, COSV101064739; called by muse, mutect2
- ZNF286A | c.1128T>C p.H376= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV67845662; called by mutect2, varscan2
- ABCC6P1 | n.630T>C | RNA (SNP) | VAF 19/186 reads (10%) | catalogued as rs765194477; called by muse, mutect2, varscan2
- AC244517.10 | c.36-10281C>A | Intron (SNP) | VAF 15/132 reads (11%) | called by muse, mutect2, varscan2
- AGAP14P | n.1120C>A | RNA (SNP) | VAF 14/257 reads (5%) | called by muse, mutect2
- ARHGAP25 | c.261+267T>C | Intron (SNP) | VAF 19/279 reads (7%) | called by muse, mutect2
- ARMCX4 | c.1038+4200C>T | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2, varscan2
- BAALC-AS2 | n.244G>T | RNA (SNP) | VAF 20/330 reads (6%) | called by muse, mutect2
- BLOC1S5-TXNDC5 | c.372+39723C>T | Intron (SNP) | VAF 9/96 reads (9%) | catalogued as rs781546635; called by muse, mutect2, varscan2
- C2orf72 | c.*45G>A | 3'UTR (SNP) | VAF 16/140 reads (11%) | catalogued as rs1395270778; called by muse, mutect2, varscan2
- CCT5 | c.1179+94A>G | Intron (SNP) | VAF 48/234 reads (21%) | called by muse, mutect2, varscan2
- CD177P1 | n.116C>T | RNA (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2
- CENPB | chr20:3787121 C>T | 5'Flank (SNP) | VAF 12/156 reads (8%) | catalogued as rs1303050588; called by muse, mutect2
- CIT | c.3714+43C>T | Intron (SNP) | VAF 23/184 reads (13%) | called by muse, mutect2, varscan2
- CSF2RA | c.1125+108C>T | Intron (SNP) | VAF 6/55 reads (11%) | catalogued as rs753052306; called by muse, mutect2, varscan2
- CTSL3P | n.216G>A | RNA (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- EIF2B5 | c.195+15C>T | Intron (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- FHOD3 | c.1197-5379del | Intron (DEL) | VAF 17/118 reads (14%) | called by mutect2, pindel, varscan2
- FRG1BP | n.398G>A | RNA (SNP) | VAF 22/297 reads (7%) | catalogued as rs79873624; called by muse, mutect2
- FRG1BP | n.399G>T | RNA (SNP) | VAF 20/292 reads (7%) | called by muse, mutect2
- GYPA | c.*42G>C | 3'UTR (SNP) | VAF 26/252 reads (10%) | catalogued as COSV99302895; called by muse, mutect2
- HDAC4 | chr2:239401921 G>T | 5'Flank (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- IL23R | c.*11T>C | 3'UTR (SNP) | VAF 27/324 reads (8%) | catalogued as rs1247038371; called by muse, mutect2
- IQSEC3 | c.3114+137G>C | Intron (SNP) | VAF 7/81 reads (9%) | catalogued as COSV100407056, COSV58290517; called by muse, mutect2
- ITPK1 | c.120+10406A>G | Intron (SNP) | VAF 4/37 reads (11%) | called by muse, varscan2
- KHDC4 | c.682-223G>A | Intron (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- LINC00692 | n.638C>A | RNA (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- LMO7 | c.3562+199G>A | Intron (SNP) | VAF 29/228 reads (13%) | catalogued as rs941276115; called by muse, mutect2, varscan2
- MIR513C | n.60T>A | RNA (SNP) | VAF 9/233 reads (4%) | called by muse, mutect2
- MIR6511A3 | chr16:16371578 C>T | 3'Flank (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- MYL2 | c.*29C>A | 3'UTR (SNP) | VAF 12/131 reads (9%) | called by muse, mutect2, varscan2
- NUTM2A | chr10:87235169 C>A | 3'Flank (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- PHPT1 | c.*126A>T | 3'UTR (SNP) | VAF 4/37 reads (11%) | called by muse, varscan2
- PLAAT4 | c.387+13C>G | Intron (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- PLOD1 | c.741+105G>T | Intron (SNP) | VAF 11/118 reads (9%) | called by muse, mutect2
- RPS13 | c.24-26C>G | Intron (SNP) | VAF 16/114 reads (14%) | catalogued as COSV57180348; called by muse, varscan2
- RS1 | c.-5G>A | 5'UTR (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- SLIT2 | c.1463-576C>T | Intron (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- SNORD115-1 | n.42A>T | RNA (SNP) | VAF 17/189 reads (9%) | called by muse, mutect2
- SNORD115-36 | n.61C>G | RNA (SNP) | VAF 15/195 reads (8%) | catalogued as rs768559957; called by muse, mutect2
- SNRPN | chr15:24980002 C>A | 3'Flank (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.2450C>T | RNA (SNP) | VAF 12/130 reads (9%) | catalogued as rs760484619; called by muse, mutect2, varscan2
- ST3GAL3 | c.1084-63C>T | Intron (SNP) | VAF 11/191 reads (6%) | called by muse, mutect2
- SYNE1 | c.2569-650G>C | Intron (SNP) | VAF 14/120 reads (12%) | called by muse, mutect2
- SYNE1 | c.2250+14G>C | Intron (SNP) | VAF 16/233 reads (7%) | called by muse, mutect2
- TBRG4 | c.-61G>T | 5'UTR (SNP) | VAF 12/97 reads (12%) | catalogued as rs1454578781; called by muse, mutect2, varscan2
- TBXAS1 | c.237-5094C>T | Intron (SNP) | VAF 10/71 reads (14%) | called by muse, mutect2, varscan2
- TRBV21OR9-2 | n.311G>A | RNA (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- XIST | n.8186C>G | RNA (SNP) | VAF 30/373 reads (8%) | called by muse, mutect2
- ZNF208 | c.226+20G>A | Intron (SNP) | VAF 7/80 reads (9%) | catalogued as rs1184885029; called by muse, mutect2
- ZNF780B | c.*2329G>A | 3'UTR (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
